Gene-level copy-number profile of tumor specimen TCGA-2H-A9GN-01A from TCGA case TCGA-2H-A9GN, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 70.3 years (25,664 days).
Specimen TCGA-2H-A9GN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.40fc0f01-8f9e-4d22-9b51-a309187aa3c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-2H-A9GN-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b8d01b06-a8e2-4e56-8b83-f086cc187408

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 15; copy number 1: 613; copy number 2: 24,254; copy number 3: 15,169; copy number 4: 16,801; copy number 5: 2,383; copy number 6: 346; copy number 7: 189; copy number 8: 13; copy number 10: 19; copy number 11: 8.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-2H-A9GN-01A-11D-A37B-01): tumor purity 0.75, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:68,477,237–68,835,541, 14 genes (within-gene range 0–2): RPL35AP33, ZFP90, RNU4-36P, AC126773.3, AC126773.6, AC126773.1, AC126773.2, CDH3, AC126773.4, AC126773.5, HSPE1P5, CDH1, RNA5SP429, AC099314.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,949 genes in 53 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:111,680,630–111,998,842, 8 genes, copy number 5 (within-gene range 3–5): INKA2, INKA2-AS1, AL049557.1, DDX20, KCND3, KCND3-IT1, KCND3-AS1, LINC01750.
- chr1:234,356,704–234,980,804, 27 genes, copy number 6–11: AL355472.1, AL355472.2, AL355472.3, COA6-AS1, COA6, TARBP1, LINC01354, AL161640.2, AL161640.3, AL161640.1, U8, IRF2BP2, AL160408.2, LINC00184, AL160408.5, AL160408.1, AL160408.4, AL160408.3, AL160408.6, LINC01132, PP2672, AL391832.4, RNY4P16, RN7SL668P, AL391832.1, AL391832.2, AL391832.3.
- chr1:237,862,175–241,677,376, 60 genes, copy number 5 (within-gene range 4–5): AL359924.1, ZP4, AL590396.1, MTCO1P38, AL590396.2, AL590396.3, MTRNR2L11, MTCYBP15, MTND6P15, MTND5P18, YWHAQP9, AL356010.2, AL356010.1, RNU6-725P, LINC01139, AL359551.1, KRT18P32, MIPEPP2, AL583825.1, AL590135.1, AC093426.2, AC093426.1, CHRM3, CHRM3-AS2, CHRM3-AS1, AL356361.2, AL356361.1, AL356361.3, RPS7P5, FMN2, AL359918.1, Y_RNA, ADH5P3, AL359918.2, Y_RNA, AL590490.1, GREM2, AL358176.1, AL358176.2, AL358176.4, AL358176.3, RNU5F-8P, AL358176.5, Y_RNA, AL365184.2, AL365184.1, THAP12P8, RGS7, RFKP1, HNRNPA1P42, AL590682.1, MIR3123, AL592076.1, AL359764.1, AL359764.2, AL359764.3, FH, KMO, OPN3, CHML.
- chr2:69,319,780–70,125,317, 22 genes, copy number 5: GFPT1, Y_RNA, NFU1, AAK1, RN7SL604P, SNORA36C, RPL36AP16, B3GALNT1P1, ANXA4, AC092431.1, GMCL1, AC019206.1, RPL23AP92, SNRNP27, MXD1, ASPRV1, PCBP1-AS1, RN7SL470P, PCBP1, AC016700.1, MRPL36P1, LINC01816.
- chr2:85,354,394–85,582,031, 17 genes, copy number 6: ELMOD3, AC062037.1, Y_RNA, RN7SL113P, AC062037.2, CAPG, AC062037.3, SH2D6, Y_RNA, RN7SL251P, Y_RNA, RPSAP22, PARTICL, MAT2A, GGCX, VAMP8, RN7SL126P.
- chr2:103,275,904–106,996,534, 72 genes, copy number 5–7 (broad region; genes not listed).
- chr2:158,968,640–160,877,850, 28 genes, copy number 7: TANC1, BTF3L4P2, RNU6-580P, GSTM3P2, MIR6888, WDSUB1, BAZ2B, AC008277.1, AC008277.2, CAPZA1P2, Y_RNA, AC009506.1, AC009961.1, RPS3AP13, MARCHF7, CD302, LY75-CD302, AC009961.3, LY75, AC009961.2, PLA2R1, ITGB6, AC092153.1, LINC02478, RBMS1, MIR4785, AC096656.1, RN7SL423P.
- chr2:164,321,933–164,843,679, 6 genes, copy number 6: CYP2C56P, GRB14, AC107075.1, COBLL1, AC019181.1, SNORA70F.
- chr2:174,719,908–177,559,299, 72 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr3:13,316,235–13,638,422, 6 genes, copy number 6 (within-gene range 2–6): NUP210, AC027124.2, AC027124.1, HDAC11-AS1, HDAC11, FBLN2.
- chr3:30,292,548–30,694,142, 7 genes, copy number 7 (within-gene range 2–7): AC025614.2, AC025614.1, U3, LINC01985, AC116035.1, TGFBR2, AC096921.1.
- chr3:142,145,454–142,448,062, 5 genes, copy number 6: RNU6-425P, GK5, XRN1, RNU6-1294P, RNU1-100P.
- chr5:74,111,690–74,536,976, 5 genes, copy number 6 (within-gene range 2–6): LINC01331, LINC01335, RN7SL814P, LINC01333, LINC01332.
- chr6:35,765,908–35,921,342, 6 genes, copy number 6: AL157823.1, CLPSL2, CLPSL1, CLPS, LHFPL5, SRPK1.
- chr6:43,705,949–43,852,333, 7 genes, copy number 6: AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1.
- chr7:2,383,698–29,195,451, 437 genes, copy number 5–6 (within-gene range 5–7) (broad region; genes not listed).
- chr7:99,876,958–100,011,634, 10 genes, copy number 7 (within-gene range 4–7): TRIM4, GJC3, AC004522.3, Y_RNA, AC004522.1, AZGP1, AC004522.4, AZGP1P1, AC004522.2, AC004522.5.
- chr8:8,317,736–8,782,479, 11 genes, copy number 5 (within-gene range 3–5): PRAG1, AC103957.1, AC103957.2, AC114550.2, AC114550.3, AC114550.1, RN7SL178P, AC087269.3, CLDN23, AC087269.2, AC087269.1.
- chr8:80,967,810–81,284,777, 9 genes, copy number 5: PAG1, AC022778.1, AC079209.2, AC079209.1, AC009902.1, UBE2HP1, AC009902.3, AC009902.2, FABP5.
- chr8:141,356,470–145,066,685, 181 genes, copy number 5 (broad region; genes not listed).
- chr9:114,491,564–115,402,644, 15 genes, copy number 6 (within-gene range 2–6): AL138895.2, AL160275.2, ATP6V1G1, TMEM268, Y_RNA, TEX53, TEX48, AL160275.1, AL390240.1, TNFSF15, AL133412.1, DELEC1, TNFSF8, TNC, AL162425.1.
- chr9:121,369,893–121,785,530, 6 genes, copy number 6 (within-gene range 2–6): AL359644.1, GGTA1, RN7SL187P, HMGB1P37, DAB2IP, AL357936.1.
- chr9:128,244,721–128,361,470, 9 genes, copy number 6: MIR199B, MIR3154, GOLGA2, SWI5, TRUB2, AL359091.3, COQ4, SLC27A4, TMSB4XP4.
- chr10:87,659,613–87,845,612, 4 genes, copy number 8: PAPSS2, ATAD1, CFL1P1, RN7SL78P.
- chr11:13,001,090–13,152,348, 4 genes, copy number 6: RASSF10-DT, RASSF10, AC013762.1, AC022878.1.
- chr11:27,040,725–27,722,058, 13 genes, copy number 6 (within-gene range 4–6): BBOX1, BBOX1-AS1, CCDC34, LGR4, LGR4-AS1, AC100771.1, LIN7C, BDNF-AS, MIR8087, RNA5SP339, AC104563.1, LINC00678, BDNF.
- chr11:34,404,663–35,661,339, 24 genes, copy number 6–8: AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1.
- chr11:108,308,519–109,823,893, 17 genes, copy number 5: C11orf65, POGLUT3, EXPH5, DDX10, RPS2P39, AP002453.1, CYCSP29, AP003027.1, AP003123.1, RNU6-654P, RNA5SP349, SNORD39, AP003049.2, C11orf87, AP003049.1, AP003102.1, LINC02715.
- chr12:95,217,746–95,515,839, 11 genes, copy number 7 (within-gene range 4–7): VEZT, Y_RNA, CBX3P5, RNU6-808P, MIR331, MIR3685, AC084879.1, AC084879.2, RNU6-735P, AC018475.1, METAP2.
- chr15:39,250,684–40,481,315, 50 genes, copy number 6: C15orf54, AC013652.2, AC109630.1, AC022196.1, THBS1, AC037198.1, AC037198.2, FSIP1, AC023908.2, AC023908.3, GPR176, AC023908.1, GPR176-DT, Y_RNA, EIF2AK4, H3P38, SRP14, SRP14-AS1, AC021755.2, AC021755.3, BMF, BMF-AS1, AC021755.1, BUB1B, PAK6, BUB1B-PAK6, AC020658.4, AC020658.3, AC020658.7, C15orf56, AC020658.6, PLCB2, ANKRD63, AC020658.5, PLCB2-AS1, AC020658.1, AC020658.2, INAFM2, CCDC9B, RNA5SP392, PHGR1, DISP2, AC013356.4, KNSTRN, IVD, BAHD1, AC013356.3, AC013356.2, CHST14, AC013356.1.
- chr15:79,989,905–81,005,788, 29 genes, copy number 6: AC015871.5, AC092701.1, Metazoa_SRP, ZFAND6, FAH, AC087761.1, CTXND1, LINC00927, AC016705.2, ARNT2, AC016705.1, AC016705.3, AC108451.1, AC108451.2, MIR5572, RNU6-380P, ABHD17C, AC023302.1, AC023302.2, CEMIP, MIR549A, AC027808.1, AC027808.2, MESD, AC068870.1, MIR4514, AC068870.2, TLNRD1, AC068870.4.
- chr15:89,784,895–90,502,239, 40 genes, copy number 6: ANPEP, AP3S2, ARPIN-AP3S2, MIR5094, AC027176.2, MIR5009, RNU6-1111P, ARPIN, RNU7-111P, AC027176.1, AC027176.3, ZNF710, MIR3174, AC087284.1, ZNF710-AS1, U7, IDH2, IDH2-DT, SEMA4B, RN7SL346P, RPS12P26, CIB1, GDPGP1, AC091167.7, TTLL13P, AC091167.2, NGRN, AC091167.6, AC091167.1, AC091167.3, AC091167.5, AC091167.4, GOLGA2P8, RN7SL736P, GABARAPL3, GABARAPL3, ZNF774, NDUFA3P4, IQGAP1, AC018946.1.
- chr17:48,026,167–48,123,601, 9 genes, copy number 5: COPZ2, MIR152, NFE2L1-DT, NFE2L1, AC004477.1, AC004477.2, CBX1, RNU6-1201P, SNX11.
- chr17:81,451,104–82,212,830, 59 genes, copy number 6 (within-gene range 4–6): MIR3186, AC110285.4, LINC01971, ACTG1, AC139149.1, FSCN2, FAAP100, NPLOC4, Y_RNA, TSPAN10, PDE6G, OXLD1, CCDC137, ARL16, HGS, MIR6786, AC139530.3, AC139530.1, MRPL12, AC139530.2, SLC25A10, GCGR, MCRIP1, PPP1R27, P4HB, AC145207.3, AC145207.9, AC145207.2, ARHGDIA, AC145207.5, AC145207.6, ALYREF, ANAPC11, NPB, PCYT2, SIRT7, MAFG, AC145207.8, MAFG-DT, PYCR1, AC145207.4, MYADML2, AC145207.1, NOTUM, AC145207.7, ASPSCR1, CENPX, LRRC45, RAC3, DCXR, AC137723.1, DCXR-DT, RFNG, GPS1, DUS1L, FASN, CCDC57, AC129510.1, AC129510.2.
- chr19:27,681,072–40,796,943, 495 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:44,699,151–44,919,349, 15 genes, copy number 6: CEACAM16, AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, AC092306.1, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1.
- chr19:45,687,454–45,914,778, 18 genes, copy number 10: SNRPD2, QPCTL, FBXO46, AC007191.1, BHMG1, SIX5, AC074212.1, DM1-AS, DMPK, AC011530.1, DMWD, RSPH6A, SYMPK, AC092301.1, FOXA3, IRF2BP1, MYPOP, NANOS2.
- chr19:54,696,604–56,368,383, 119 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr19:57,487,711–58,605,223, 99 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:30,377,372–64,313,132, 893 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 179. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
